Somatic mutation profile of tumor specimen 0DSP2C from CCDI case PBCHVN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic fibroma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 16.9 years (6,177 days).
Specimen 0DSP2C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fea31f4b-6d4c-4eec-a83c-f68acfd923e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSP2H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b126a2d7-385e-4562-8f89-c17b823ea77a

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 337/909 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- S1PR5 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 146/294 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1194671448, COSV100330709, COSV61013438; called by muse, mutect2
- FMNL1 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 230/584 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SOX8 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBQLN2 | c.1644T>G p.S548R | Missense Mutation (SNP) | VAF 289/329 reads (88%) | SIFT tolerated (0.16); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MUC16 | c.18780G>A p.A6260= | Silent (SNP) | VAF 281/704 reads (40%) | catalogued as rs370104717; called by muse, mutect2, varscan2
- RNF31 | c.123T>C p.S41= | Silent (SNP) | VAF 29/645 reads (4%) | called by muse, mutect2
- AGER | c.*34C>G | 3'UTR (SNP) | VAF 73/87 reads (84%) | called by muse, mutect2, varscan2
- CYB5D2 | c.*77T>C | 3'UTR (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
